Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMX, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMX-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

DIAGNOSIS:

RADICAL CYSTECTOMY WITH ILEAL CONDUIT:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER (C):

- INVASIVE POORLY DIFFERENTIATED UROTHELIAL CARCINOMA (7.5 X 3.5 X 2 CM), GRADES 3 AND 4/4, GROSSLY EXTENDING THROUGH BLADDER WALL INTO PERIVESICAL SOFT TISSUE AND APPROACHING DEEP ANTERIOR VAGINAL WALL (SEE COMMENT)
- RANDOM BLADDER MUCOSA INCLUDING RIGHT AND LEFT LATERAL WALLS, TRIGONE AND LEFT URETEROVESICAL JUNCTION SHOWING UROTHELIAL CARCINOMA IN SITU (FLAT LESION)
- LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- SURGICAL RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY
- NON-NEOPLASTIC BLADDER SHOWING CHRONIC INFLAMMATION
- ANTERIOR VAGINAL WALL, BENIGN SQUAMOUS MUCOSA
- LEFT OVARY, BENIGN SIMPLE SEROUS CYST AND PHYSIOLOGIC CHANGES WITHOUT EVIDENCE OF ATYPIA OR MALIGNANCY

PART OF ANTERIOR VAGINAL WALL (D):

- PREDOMINANTLY BENIGN FIBROMUSCULAR TISSUE EXHIBITING EXTENSIVE MUCOSAL EROSION
- SMALL RESIDUAL INTACT AREA OF SQUAMOUS MUCOSA WITH NO EVIDENCE OF DYSPLASIA OR MALIGNANCY

RIGHT LYMPH NODE OF CLOQUET (E):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT EXTERNAL ILIAC (F):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT OBTURATOR HYPOGASTRIC LYMPH NODE (G):

- NO MALIGNANCY IDENTIFIED IN 13 LYMPH NODES EXAMINED (0/13)

LEFT EXTERNAL ILIAC LYMPH NODE (H):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT OBTURATOR HYPOGASTRIC LYMPH NODE (I):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)
- NON-NECROTIZING GRANULOMATOUS INFLAMMATION (SEE COMMENT)

LEFT PROXIMAL URETER (J):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (K):

- BENIGN URETER

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder NOS
C67.9
JW 3/26/14

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: NO MALIGNANCY IDENTIFIED IN 26 LYMPH NODES
EXAMINED (0/26)

PATHOLOGIC TNM STAGE: BLADDER: pTis, T3bNOMX

Electronically signed by
Verified:

COMMENT:

Representative sections of invasive carcinoma are submitted for p53 assay by immunohistology, results of which will be reported in an addendum.

There are two lymph nodes identified showing non-necrotizing ill-defined granulomas. Histochemical stains for acid fast bacilli (AFB) and fungi (GMS) are negative.

SPECIMEN SOURCE:

- A: "Right distal ureter-F/S"
- B: "Left distal ureter-F/S"
- C: "Bladder"
- D: "Part of anterior vaginal wall"
- E: "Right LN of cloquet"
- F: "Right external iliac"
- G: "Right obturator hypogastric LN"
- H: "Left external iliac LN"
- I: "Left obturator hypogastric LN"
- J: "Left proximal ureter"
- K: "Right proximal ureter"

CLINICAL INFORMATION:

Pre-op Dx: Bladder cancer
Post-op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O R. and labeled "Right distal ureter-F/S". It consists of a segment of ureter with surrounding fat measuring 0.3 cm. The ureter itself measures 0.3 cm in length x 0.3 cm diameter. The specimen is entirely submitted for frozen section in AFS.

B: The specimen is received fresh from the O R. and labeled "Left distal ureter-F/S". It consists of a strip of tan tissue measuring 0.9 cm in length x 0.2 x 0.2 cm. The specimen is entirely submitted for frozen section in BFS.

C: The specimen is received fresh from the O R. and labeled "Bladder". It consists of a urinary bladder with attached peritoneum and anterior vaginal wall measuring overall 19 x 12 x 5.5 cm. The peritoneum measures 19 x 9 x 0.1 cm and shows focal fine reddish-tan adhesions. Identified on the posterior part of the specimen is the anterior vaginal wall measuring 6 x 5 cm covered by tan glistening mucosa. Also identified attached to the left side of the specimen is tan-brown ovarian tissue measuring 2.5 x 1.3 x 1.3 cm. The outer surface is tan-brown smooth and glistening. On sectioning, there is a cyst measuring 2 cm in greatest dimension filled with serous fluid. The inner wall of the cyst is tan-brown smooth

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

Location

and glistening with no excrescences identified. Also identified in the same area is ill-defined tubular tissue measuring 4 cm in length x 0.8 cm in average external diameter suspicious for fallopian tube. The bladder itself measures 9 x 7 x 4 cm. The surgical margins are inked black and the bladder is opened. On opening the specimen anteriorly, it reveals a tan-brown sessile polypoid, exophytic mass. It is located in the trigone / bladder neck area, measures 7.5 x 3.5 x 2 cm and is almost circumferential sparing only 1 cm of the anterior bladder wall. It extends to the left lateral wall. Also identified is another sessile tumor on the left lateral wall, located 1.5 cm from the previous and measuring 1.9 x 0.9 x 0.8 cm. The remainder of the bladder mucosa shows multiple foci of submucosal hemorrhage and is hyperplasia. The uninvolved bladder wall is 0.9 cm in thickness. No diverticula are identified. Sectioning of the tumor shows it invading through the muscularis propria into the perivesical fat. Grossly, the tumor is located 1 cm away from the nearest perivesical inked margin in the left lateral wall. The tumor is seen abutting but not involving the left ureterovesical junction and is 0.5 cm away from the right ureterovesical junction. The tumor is also 1.5 cm away from the proximal urethra and 3.5 cm away from the distal urethra. The urethra measures 2 cm in length x 1.2 cm in average circumference covered with pale tan glistening mucosa. Both ureterovesical junctions are identified, probed and opened revealing the right attached ureter 7 cm in length x 0.4 cm in circumference, and left 5.5 cm in length x 0.9 cm in circumference. Both ureteral mucosae are unremarkable. Representative sections are submitted in 22 cassettes.

D: The specimen is received in formalin and labeled "Part of anterior vaginal wall". It consists of a tan fibrous irregular tissue segment measuring overall 3.5 x 1.5 x 1 cm. The tissue is serially sectioned into four pieces and totally embedded in 2 cassettes.

E: The specimen is received in formalin and labeled "Right LN of cloquet". It consists of fibrofatty tissue with a lymph node measuring 2.5 x 1 x 0.5 cm. The lymph node is bisected and totally embedded one cassette.

F: The specimen is received in formalin and labeled "Right external iliac". It consists of fibrofatty tissue with lymph nodes measuring 4 x 3 x 0.5 cm. The largest lymph node measures 4 x 1 x 0.5 cm which is trisected and submitted in two cassettes, and the remainder of the tissue is submitted in a third cassette.

G: The specimen is received in formalin and labeled "Right obturator hypogastric LN". It consists of fibrofatty tissue with lymph nodes measuring 7 x 5 x 2 cm. The specimen is totally embedded in three cassettes.

H: The specimen is received in formalin and labeled "Left external iliac LN". It consists of fibrofatty tissue with lymph nodes measuring 4 x 4 x 0.8 cm. The specimen is totally embedded in three cassettes.

I: The specimen is received in formalin and labeled "Left obturator hypogastric LN". It consists of fibrofatty tissue with lymph nodes measuring 8 x 3 x 0.8 cm. The largest lymph node measures 8 x 1 x 0.8 cm. It is trisected and totally submitted in three cassettes, and the remainder of the tissue is submitted in a fourth cassette.

J: The specimen is received in formalin and labeled "Left proximal ureter". It consists of a segment of ureter measuring 1.2 cm in length x 0.6 cm in diameter. The specimen is trisected and totally embedded in one cassette.

K: The specimen is received in formalin and labeled "Right proximal ureter". It consists of a segment of ureter measuring 1.6 cm in length x 0.6 cm in diameter. The specimen is totally embedded in one cassette.

SECTIONS:

[page 4 of 5]
Collected	Ordered by	Location
AFS:		frozen section, right distal ureter
BFS:		frozen section, left distal ureter
C1:		bladder; urethral margin
C2:		anterior wall of bladder
C3:		right lateral wall of bladder
C4:		right ureterovesical junction
C5:		dome of bladder
C6:		posterior wall of bladder
C7:		left ureterovesical junction
C8:		left lateral wall of bladder
C9-10:		trigone with tumor and anterior vaginal wall
C11-12:		full thickness tumor from left lateral wall
C13:		tumor from right lateral wall
C14:		right lateral tumor
C15:		tumor, random
C16:		tumor # 2 in left posterior lateral wall
C17:		longitudinal perpendicular section of urethra
C18-19:		ovary
C20:		ill-defined tubular tissue
C21:		possible right perivesical lymph nodes
C22:		possible left perivesical lymph nodes
D1-2:		part of anterior vaginal wall
E:		right lymph node of Cloquet
F1,2:		right external iliac lymph nodes; largest lymph node
F3:		remaining tissue
G1-3:		right obturator hypogastric lymph nodes
H1-3:		left external iliac lymph nodes
I1-4:		left obturator hypogastric lymph nodes
J:		left proximal ureter
K:		right proximal ureter

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter
- no high grade atypia or tumor identified

BFS: Left distal ureter
- no high grade atypia or tumor identified

MICROSCOPIC EXAMINATION:

A-B: See final microscopic-diagnoses.

C: Sections of the bladder representing the sessile polypoid mass in the trigone and left lateral wall show deeply invasive poorly differentiated urothelial carcinoma (C7,8-15), grades 3 and 4 of 4, extending into perivesical soft tissue and associated with multiple foci of lymphovascular invasion. Associated with invasive tumor are foci of in situ urothelial carcinoma (flat lesion). Additional multiple random sections of bladder including trigone, right lateral wall, left lateral wall, dome, posterior wall and left ureterovesical junction show urothelial carcinoma in situ (C2,3,5,6,8,15,16). All resection margins are free of dysplasia and malignancy. Sections of the left ovary show a simple serous cyst and corpora albicantia. The tubular structure grossly identified from the area of the ovary is consistent with the round ligament.

D-K: See final microscopic-diagnoses.

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

Source: NCI Genomic Data Commons file bb3d0ba5-2b61-497c-9696-216ee802db52 (TCGA-XF-AAMX.22526530-46B1-4DB8-A1EB-2D97AB18FD63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).